FM case AD1664 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/b059d7fd-bdae-49bf-bbad-10b4c89ff6fd

Male, 66.7 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the bladder; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
